Somatic mutation profile of tumor specimen MP2PRT-PATVXW-TMP1-A (aliquot MP2PRT-PATVXW-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATVXW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,670 days).
Specimen MP2PRT-PATVXW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c86ddd83-b94c-4725-8ff3-44398f4936c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVXW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVXW-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ecf0fc-c7c1-4a89-a035-b6b8dd55fe35

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 2, In Frame Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 27/197 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CENPU | c.48C>T p.G16= | Splice Region (SNP) | VAF 15/64 reads (23%) | catalogued as rs374369387; called by muse, mutect2, varscan2
- CTSC | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 93/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777000878, CM151772, COSV57059529; called by muse, mutect2, varscan2
- FLT3 | c.1780_1781insCCC p.F594delinsSL | In Frame Ins (INS) | VAF 24/88 reads (27%) | catalogued as COSV54045432, COSV54059397, COSV54065517, COSV54066004, COSV54071634, COSV54075177, COSV54075959, COSV54078222, COSV99608085; called by mutect2, pindel*, varscan2
- GRXCR1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 43/586 reads (7%) | catalogued as rs754115014, COSV101295744, COSV67671089, COSV67674884; called by muse, mutect2
- HTR4 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 46/471 reads (10%) | PolyPhen benign (0.067); catalogued as rs575843785, COSV73027095; called by muse, mutect2, varscan2
- LIPG | c.966T>A p.N322K | Missense Mutation (SNP) | VAF 123/760 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASD1 | c.514_516dup p.A172dup | In Frame Ins (INS) | VAF 323/1014 reads (32%) | called by mutect2, pindel, varscan2
- ZNF391 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
